Somatic mutation profile of tumor specimen TCGA-AK-3429-01A (aliquot TCGA-AK-3429-01A-02D-1386-10) from TCGA case TCGA-AK-3429, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 54.3 years (19,849 days).
Specimen TCGA-AK-3429-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e40778b-8d12-47aa-8c88-e21401e89632.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3429-10A (Blood Derived Normal), aliquot TCGA-AK-3429-10A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/507cc12c-510a-4b9e-a6a6-1ebb63b733f5

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Del 2, Splice Site 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADNP2 | c.970C>A p.P324T | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs571198421, COSV51536151; called by muse, mutect2, varscan2
- ANGPT1 | c.576-1G>C p.X192_splice | Splice Site (SNP) | VAF 73/369 reads (20%) | catalogued as COSV52430396, COSV52459986; called by muse, mutect2, varscan2
- ATP12A | c.1882-1G>T p.X628_splice | Splice Site (SNP) | VAF 22/354 reads (6%) | catalogued as COSV54512211; called by muse, mutect2
- CCDC171 | c.2785A>G p.R929G | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as COSV52633931; called by muse, mutect2, varscan2
- DDA1 | c.123C>A p.Y41* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV63289376; called by muse, mutect2, varscan2
- EXO5 | c.43T>G p.S15A | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.956); catalogued as COSV56415236; called by muse, mutect2, varscan2
- FLT1 | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369255421, COSV56721532; called by muse, mutect2
- FLT3 | c.1615C>A p.Q539K | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0.1); catalogued as COSV54043533; called by muse, mutect2, varscan2
- MAGI2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV62633287; called by muse, mutect2
- NAB1 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV61608118; called by muse, mutect2, varscan2
- NCOR2 | c.3175C>T p.P1059S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV62292977; called by muse, mutect2, varscan2
- RECQL4 | c.3414G>T p.Q1138H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as COSV56739227; called by muse, varscan2
- SNX29 | c.686T>C p.I229T | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV60050563; called by muse, mutect2, varscan2
- TTC3 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1389056749, COSV61285715; called by muse, mutect2
- UBR1 | c.3239T>G p.I1080S | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV51925955; called by muse, mutect2, varscan2
- SGK1 | c.3_4del p.M1_?2 | Frame Shift Del (DEL) | VAF 19/104 reads (18%) | called by mutect2, pindel, varscan2
- TET2 | c.2465_2466del p.T822Nfs*23 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- FAM3A | c.249G>A p.G83= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV59194034; called by muse, mutect2, varscan2
- NOP2 | c.1410C>A p.S470= (on ENST00000322166 / NM_001258308.2; = p.S466= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV59109378; called by muse, mutect2, varscan2
- PCLO | c.9456G>A p.T3152= | Silent (SNP) | VAF 10/129 reads (8%) | catalogued as rs915755475, COSV61615236; called by muse, mutect2
- XRN1 | c.4438T>C p.L1480= | Silent (SNP) | VAF 54/249 reads (22%) | catalogued as COSV53807824; called by muse, mutect2, varscan2
